Somatic mutation profile of tumor specimen HCM-BROD-0003-C71-01A (aliquot HCM-BROD-0003-C71-01A-01D-A77E-36) from HCMI case HCM-BROD-0003-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 82.1 years (29,995 days).
Specimen HCM-BROD-0003-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da2c45c6-f909-4980-89f0-0e191018fc25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0003-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0003-C71-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8adc462-c52d-4594-8330-7fc687016d67

The open-access MAF lists 95 somatic variants for this specimen: 57 protein-altering or splice-affecting, 21 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 21, Intron 10, Nonsense Mutation 5, 3'UTR 4, Frame Shift Del 3, RNA 2, In Frame Del 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 401/437 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANHX | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 105/160 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs566321789; called by muse, mutect2, varscan2
- ANKS1B | c.2412G>T p.E804D | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs759070307; called by muse, mutect2, varscan2
- ANO1 | c.1939C>T p.R647* | Nonsense Mutation (SNP) | VAF 87/289 reads (30%) | catalogued as COSV60283632; called by muse, mutect2, varscan2
- C20orf194 | c.3463C>T p.R1155W | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs377127941; called by muse, mutect2, varscan2
- CFAP43 | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 173/205 reads (84%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as rs781153112, COSV63852972; called by muse, mutect2, varscan2
- CNGB1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 223/383 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as rs1474407023; called by muse, mutect2, varscan2
- CPA3 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as rs374800491; called by muse, mutect2, varscan2
- DSPP | c.2529_2537del p.S847_D849del | In Frame Del (DEL) | VAF 493/868 reads (57%) | catalogued as rs1560479204; called by mutect2, varscan2
- FRMPD2 | c.3230del p.K1077Sfs*6 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as COSV100563975; called by mutect2, varscan2
- KIDINS220 | c.3454C>T p.P1152S | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1167491479; called by muse, mutect2, varscan2
- LEFTY2 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 181/673 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.183); catalogued as rs1195590424; called by muse, mutect2, varscan2
- MGAT1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 109/403 reads (27%) | PolyPhen benign (0.017); catalogued as rs1206612538, COSV57134679; called by muse, mutect2, varscan2
- MINDY4 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 97/308 reads (31%) | catalogued as rs1279694160, COSV54670818, COSV54671079; called by muse, mutect2, varscan2
- NEFM | c.870G>T p.E290D | Missense Mutation (SNP) | VAF 358/629 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as rs760454116; called by muse, mutect2, varscan2
- ODAM | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs758616960; called by muse, mutect2
- OR5T2 | c.619T>A p.F207I | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57591826; called by muse, mutect2, varscan2
- PKHD1 | c.7030T>C p.F2344L | Missense Mutation (SNP) | VAF 238/264 reads (90%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs756780930; called by muse, mutect2, varscan2
- PLCH2 | c.2770C>T p.R924W | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1445934710; called by muse, mutect2, varscan2
- PPP6R1 | c.2170C>T p.P724S | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs767483312; called by muse, mutect2, varscan2
- RHPN2 | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 213/239 reads (89%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs1347761451, COSV54275765; called by muse, mutect2, varscan2
- RUFY1 | c.1731G>A p.M577I | Missense Mutation (SNP) | VAF 104/185 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100106485; called by muse, mutect2
- SELP | c.2369C>T p.T790M | Missense Mutation (SNP) | VAF 165/264 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.373); catalogued as rs75278502; called by muse, mutect2, varscan2
- SNRPN | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 71/137 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.435); catalogued as rs777253872, COSV57597975; called by muse, mutect2, varscan2
- THBS1 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs781417873, COSV52955157; called by muse, mutect2, varscan2
- TRIM49 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 171/916 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs141552770, COSV61672343; called by muse, mutect2, varscan2
- TRMU | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 271/301 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99324468; called by muse, mutect2, varscan2
- UGT2A1 | c.1461C>G p.H487Q | Missense Mutation (SNP) | VAF 98/338 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99684803; called by muse, mutect2
- UGT8 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 126/202 reads (62%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs114818124; called by muse, mutect2, varscan2
- UMOD | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 164/615 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs387907550, COSV56775644; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC5CL | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 209/237 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs1327927428; called by muse, mutect2, varscan2
- AARS1 | c.1769G>A p.W590* | Nonsense Mutation (SNP) | VAF 100/341 reads (29%) | called by muse, mutect2, varscan2
- AL035460.1 | c.457G>T p.V153L | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ALPK2 | c.109+1G>A p.X37_splice | Splice Site (SNP) | VAF 78/158 reads (49%) | called by muse, mutect2, varscan2
- AOC1 | c.1604A>T p.K535M | Missense Mutation (SNP) | VAF 91/146 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- CBY2 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- DYNC2H1 | c.8978G>C p.G2993A | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FANCM | c.722T>A p.I241N | Missense Mutation (SNP) | VAF 98/108 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FN1 | c.1828G>C p.G610R | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT tolerated (0.93); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSIP2 | c.13737C>A p.F4579L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAREM1 | c.1718C>T p.S573L | Missense Mutation (SNP) | VAF 136/218 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRRIQ4 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 121/254 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- MAST4 | c.2167A>T p.T723S (on ENST00000403625 / NM_001164664.2; = p.T534S on NM_015183.3) | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPL1 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2
- NDUFA2 | c.237G>C p.L79F | Missense Mutation (SNP) | VAF 120/400 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOL8 | c.1149A>T p.E383D | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- OR4C3 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTOGL | c.2371C>G p.L791V (on ENST00000547103; = p.L782V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/168 reads (59%) | SIFT tolerated (0.81); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PTEN | c.891del p.Q298Kfs*9 | Frame Shift Del (DEL) | VAF 138/224 reads (62%) | called by mutect2, pindel, varscan2
- RASSF9 | c.878G>A p.S293N | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- RPA1 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 147/169 reads (87%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SH2D3A | c.1295G>A p.W432* | Nonsense Mutation (SNP) | VAF 160/182 reads (88%) | called by muse, mutect2, varscan2
- SLC22A2 | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 57/69 reads (83%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLCO6A1 | c.2051C>G p.T684S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- SNX25 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 100/346 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- TG | c.3567G>T p.W1189C | Missense Mutation (SNP) | VAF 191/531 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMTC4 | c.2121del p.K707Nfs*23 (on ENST00000376234 / NM_001350577.2; = p.K726Nfs*23 on NM_032813.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 46/119 reads (39%) | called by mutect2, pindel, varscan2
- ABCD1 | c.1674C>T p.I558= | Silent (SNP) | VAF 352/760 reads (46%) | called by muse, mutect2, varscan2
- ADH1A | c.942C>G p.T314= | Silent (SNP) | VAF 62/287 reads (22%) | called by muse, mutect2, varscan2
- ASB10 | c.1191C>T p.V397= (on ENST00000420175 / NM_001142459.2; = p.V382= on NM_080871.4) | Silent (SNP) | VAF 60/190 reads (32%) | catalogued as rs753462958; called by muse, mutect2, varscan2
- CFAP61 | c.1959C>T p.N653= | Silent (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- COX11 | c.117G>A p.E39= | Silent (SNP) | VAF 287/700 reads (41%) | catalogued as rs950513526; called by muse, mutect2, varscan2
- FAM117A | c.552C>T p.H184= | Silent (SNP) | VAF 191/374 reads (51%) | catalogued as rs1166086388; called by muse, mutect2, varscan2
- FANCM | c.723C>A p.I241= | Silent (SNP) | VAF 97/107 reads (91%) | called by muse, mutect2, varscan2
- ITGAD | c.918G>A p.A306= | Silent (SNP) | VAF 73/261 reads (28%) | catalogued as rs141660381; called by muse, mutect2, varscan2
- KANK3 | c.963G>A p.E321= | Silent (SNP) | VAF 155/180 reads (86%) | called by muse, mutect2, varscan2
- LCK | c.213C>T p.S71= | Silent (SNP) | VAF 127/197 reads (64%) | called by muse, mutect2, varscan2
- LILRB1 | c.1482C>T p.L494= | Silent (SNP) | VAF 143/180 reads (79%) | catalogued as rs1466196752; called by muse, mutect2, varscan2
- NDC80 | c.936A>G p.A312= | Silent (SNP) | VAF 53/110 reads (48%) | called by muse, mutect2, varscan2
- NPTX2 | c.1038C>T p.P346= | Silent (SNP) | VAF 123/215 reads (57%) | catalogued as rs187478353, COSV99675129; called by muse, mutect2, varscan2
- POM121L12 | c.267G>A p.P89= | Silent (SNP) | VAF 91/316 reads (29%) | catalogued as rs772385441, COSV101374858, COSV68692323; called by muse, mutect2, varscan2
- RBMXL3 | c.441C>A p.P147= | Silent (SNP) | VAF 121/267 reads (45%) | called by muse, mutect2, varscan2
- RINT1 | c.186G>A p.K62= | Silent (SNP) | VAF 63/114 reads (55%) | catalogued as COSV57557752; called by muse, mutect2, varscan2
- TMEM132C | c.504A>G p.P168= | Silent (SNP) | VAF 240/423 reads (57%) | catalogued as rs761907910; called by muse, mutect2, varscan2
- TRABD2B | c.756C>A p.I252= | Silent (SNP) | VAF 112/349 reads (32%) | called by muse, mutect2, varscan2
- WWP2 | c.666C>T p.V222= | Silent (SNP) | VAF 173/306 reads (57%) | catalogued as rs1217318959; called by muse, mutect2, varscan2
- ZIC2 | c.309G>T p.A103= | Silent (SNP) | VAF 81/176 reads (46%) | called by muse, mutect2, varscan2
- ZNF674 | c.24G>A p.L8= | Silent (SNP) | VAF 193/463 reads (42%) | called by muse, mutect2, varscan2
- BPTF | c.8640-714_8640-712del | Intron (DEL) | VAF 48/117 reads (41%) | called by pindel, varscan2
- CELF4 | c.1165+35A>G | Intron (SNP) | VAF 158/247 reads (64%) | called by muse, mutect2, varscan2
- DCC | c.3163+152G>A | Intron (SNP) | VAF 66/118 reads (56%) | catalogued as rs1027237408; called by muse, mutect2, varscan2
- FRMPD2B | n.647del | RNA (DEL) | VAF 30/117 reads (26%) | called by mutect2, varscan2
- GABRE | c.784+1301G>T | Intron (SNP) | VAF 156/380 reads (41%) | called by muse, mutect2, varscan2
- IRF5 | c.195+842C>T | Intron (SNP) | VAF 24/87 reads (28%) | catalogued as rs1269749804; called by muse, mutect2, varscan2
- LMX1B | c.*41G>T | 3'UTR (SNP) | VAF 57/184 reads (31%) | called by muse, mutect2, varscan2
- MAX | c.172-6220G>A | Intron (SNP) | VAF 179/206 reads (87%) | catalogued as rs188440951; called by muse, mutect2, varscan2
- MGAT5B | c.1025+7507G>A | Intron (SNP) | VAF 62/147 reads (42%) | called by muse, mutect2, varscan2
- NAT8L | c.*25C>T | 3'UTR (SNP) | VAF 33/109 reads (30%) | called by muse, mutect2, varscan2
- PALB2 | c.2834+24T>C | Intron (SNP) | VAF 99/174 reads (57%) | called by muse, mutect2, varscan2
- PIP5K1B | c.*37G>A | 3'UTR (SNP) | VAF 45/155 reads (29%) | catalogued as rs771826277, COSV99598505; called by muse, mutect2, varscan2
- RPGR | c.2520+1187del | Intron (DEL) | VAF 54/177 reads (31%) | catalogued as rs1186795749, CD033277; called by mutect2, pindel
- RPS26P15 | n.150C>A | RNA (SNP) | VAF 128/578 reads (22%) | called by muse, mutect2, varscan2
- SMARCA1 | c.2329-9C>A | Intron (SNP) | VAF 41/101 reads (41%) | called by muse, mutect2, varscan2
- TFB1M | c.-25G>A | 5'UTR (SNP) | VAF 292/342 reads (85%) | catalogued as rs931406879; called by muse, mutect2
- VAPB | c.*5165G>A | 3'UTR (SNP) | VAF 13/88 reads (15%) | catalogued as rs1450622752; called by muse, mutect2, varscan2
